TARGET case TARGET-30-PATFTR — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8ed1dc66-0db4-5d9d-a8ea-115c2480243b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 0 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C49.5; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Classification of tumor: primary; Age at diagnosis: 0.5 years (193 days); Year of diagnosis: 2010; Days to last follow up: 3,362 days (9.2 years); Cog neuroblastoma risk group: Intermediate Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 3; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 60.
   Treatment given: Protocol identifier: ANBL0531.
   Treatment given: Protocol identifier: AEPI07N1.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 3,362 days (9.2 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,362; Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PATFTR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-30-PATFTR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Validation_20230322.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 3362
- Protocol: ANBL00B1, ANBL0531, AEPI07N1
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.58
- Histology: Favorable
- MKI: Low
